Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-4865, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-4865-01A (Primary Tumor).

[page 1 of 4]
Pathology Report

Accession Number: [REDACTED] Report Status: Amend/Adder
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

CASE: [REDACTED]

PATIENT: [REDACTED]

***** Addended Report *****

TCGA-CZ-4865

PATHOLOGIC DIAGNOSIS:

SPECIMEN LABELED "LEFT KIDNEY" (475 gm):

RENAL CELL CARCINOMA, clear cell type (3.0 cm).

Fuhrman nuclear grade II of IV.

Tumor is confined to the kidney and does not involve perihilar or perinephric adipose tissue.

Artery, vein and ureter resection margins are negative for tumor.

No lymphovascular invasion is identified.

Simple cyst (10 cm).

Non-neoplastic renal parenchyma will be evaluated by the Renal Pathology

Service and the results will be reported in an addendum.

B. SPECIMEN LABELED "RETROPERITONEAL LYMPH NODES":

Fibroadipose tissue with no tumor present.

No lymphoid tissue identified (the specimen was entirely submitted for histologic analysis).

AJCC Classification (6th Edition): T1a NX MX.

CLINICAL DATA:

History: 70 yo female, incidental L renal mass -> RCC by bx.

PMH: COPD, breast ca

Operation: L radical nephrectomy

Clinical Diagnosis: Renal cell ca L kidney

TISSUE SUBMITTED:

A/1. L kidney

B/2. Regional retroperitoneal lymph nodes

GROSS DESCRIPTION:

The specimen is received fresh, in two parts, each labeled with the patients name and unit number.

Part A, "1. L kidney", consists of 475g nephrectomy specimen, consisting of a left kidney (18.2 x 9.0 x 5.9 cm) including a thin-walled cyst (10 x 9.5 x 5.9 cm) in the lower pole (lined by smooth walls and filled with a thin, serous fluid), the ureter (6.0 cm length, 0.3 cm diameter), the renal artery (1.2 cm length, 0.9 cm diameter), and the renal vein (0.5 cm length, 1.1 cm diameter). The specimen has been previously inked and bivalved, revealing a circumscribed, tan/yellow, focally hemorrhagic mass (3.0 x 2.6 x 2.5 cm) in the upper/mid kidney abutting the renal pelvis. The mass is 1.2 cm from the renal vein resection margin, 1.0 cm from the renal artery resection margin, 8.3 cm from the ureteral resection margin, and 0.3 cm from the closest black-inked deep margin (hilar fat). The mass does not appear to grossly invade the renal pelvis. The remaining renal parenchyma is unremarkable. The corticomedullary junction is distinct. A representative section of tumor has been submitted to Cytogenetics, the Tissue Bank, and for quick-fix, and a representative section of normal tissue has been submitted to the Tissue Bank (cortex and medulla), for EM (cortex), and for IF (cortex).

Micro A1: vascular ureteral margins, multi frag [REDACTED]

Micro A2: quick-fixed section of tumor, 1 frag, [REDACTED]

Micro A3: tumor and renal vein, 1 frag, [REDACTED]

Micro A4: tumor and closest deep margin (inked black), 1 frag, [REDACTED]

Micro A5: tumor and renal pelvis, 1 frag, [REDACTED]

[page 2 of 4]
Micro A6: lower pole cyst wall, cyst w/respect to uninvolved renal parenchyma, 3 frag, [REDACTED]

Part B, "2. retroperitoneal lymph nodes", consists of multiple fragments of soft tan/yellow adipose tissue (4 x 3.5 x 1.2 cm in aggregate). There are no palpable lymph nodes. The specimen is entirely submitted.

Micro B1-B2: multi frag/cass, [REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

ADDENDUM

RENAL PATHOLOGY EVALUATION OF KIDNEY PARENCHYMA:

LEFT KIDNEY, NEPHRECTOMY:

SIMPLE CYSTS (approximately 5; up to 10 cm), MOST LIKELY RESULTING FROM URINARY OBSTRUCTION AND RETENTION, WITH COMPRESSION-RELATED CHANGES OF THE ADJACENT KIDNEY PARENCHYMA

MILD CHRONIC CHANGES OF THE KIDNEY PARENCHYMA, INCLUDING

- FOCAL GLOBAL AND SEGMENTAL GLOMERULOSCLEROSIS, MILD (9% OF GLOMERULI), MOST LIKELY SECONDARY TO FUNCTIONAL ADAPTATIONS FROM NEPHRON LOSS
- TUBULAR ATROPHY AND INTERSTITIAL FIBROSIS, MILD (10-15% OF CORTEX)
- ARTERIAL AND ARTERIOLAR SCLEROSIS, MODERATE

(SEE NOTE)

PAPILLARY ADENOMA (0.1 cm)

NOTE:

Mild chronic changes are present in the kidney parenchyma, not including the loss of nephrons from cyst and tumor-related compression. Because these changes are a result of functional adaptations to nephron loss from any glomerular, tubular, interstitial, vascular, or mass-replacing process, a similar degree of chronic damage would be expected in the contralateral kidney. Incidental note is made of a papillary adenoma.

The kidney parenchyma has been reviewed by [REDACTED] Renal Pathology Service.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block A6) were evaluated using HE, PAS, Jones silver methenamine, and AFOG (trichrome) stains.

The sample consists of cortex and medulla. There are 157 glomeruli present away from the cyst wall, of which 12 are globally sclerosed and 2 are segmentally sclerosed. Extensive glomerulosclerosis is present adjacent to the cyst wall; the parenchyma in this area also shows compression-related changes and entrapped tubules, vessels with smooth muscle hypertrophy, and glomeruli. The remaining glomeruli show no significant expansion of the mesangial areas. There are no discernible craters or spikes, but a few double contours of the glomerular capillary wall basement membranes are seen. Approximately 10-15% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries and arterioles exhibit a moderate degree of sclerosis.

[page 3 of 4]
Pathology Report

GROSS DESCRIPTION:

Additional sections were submitted to further characterize the nature
cyst wall

Micro Non-neoplastic kidney and cyst wall, 1 frag each,

[Clinical history: Breast cancer, severe COPD, creatinine 0.6-1.1]

[page 4 of 4]
Pathology Report

Accession Number: [REDACTED]
Type: Cytogenetics
CASE: [REDACTED]
PATIENT: [REDACTED]
Cytogeneticist: [REDACTED]

Report Status: Final

KARYOTYPE: 46,XX,+X,der(3)t(3;8)(p2?1;q2?3),-8 [10]

METAPHASES COUNTED: 10 ANALYZED: 7 SCORED: 3 BANDING: GTG

INTERPRETATION:

All metaphases contained clonal aberrations including loss of the short arm of chromosome 3, which is a characteristic finding in renal cell carcinoma, clear cell type.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

? RCC

Source: NCI Genomic Data Commons file 0d4bc9ef-07eb-49f4-a6eb-dec7a462de70 (TCGA-CZ-4865.B44898D2-5B0E-4F20-BA5F-EE1E10BB156B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).